Somatic mutation profile of tumor specimen TCGA-BP-5000-01A (aliquot TCGA-BP-5000-01A-01D-1462-08) from TCGA case TCGA-BP-5000, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 40.7 years (14,868 days).
Specimen TCGA-BP-5000-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20d94b8f-2ced-4d84-b636-7489f675c2a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5000-11A (Solid Tissue Normal), aliquot TCGA-BP-5000-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9efd6dc-5373-444d-9334-b446e9cd4ca9

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 12, Frame Shift Del 4, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.3266G>A p.C1089Y | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1401813809, COSV52703754, COSV52709920; called by muse, mutect2
- AC109583.1 | c.1010G>T p.S337I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV58405070; called by muse, mutect2
- ADAM15 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV55124891; called by muse, mutect2, varscan2
- AGBL1 | c.2553C>T p.G851= | Splice Region (SNP) | VAF 32/185 reads (17%) | catalogued as COSV66847192; called by muse, mutect2, varscan2
- AHNAK | c.13724A>C p.K4575T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV57202194; called by muse, mutect2, varscan2
- BCORL1 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV54388840; called by muse, mutect2, varscan2
- C2CD3 | c.1568A>G p.Q523R | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.068); catalogued as COSV58088924; called by muse, mutect2, varscan2
- C8orf34 | c.455G>A p.W152* | Nonsense Mutation (SNP) | VAF 20/124 reads (16%) | catalogued as COSV61369293; called by muse, mutect2, varscan2
- CDCP2 | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61282339; called by muse, mutect2, varscan2
- CLYBL | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59216188, COSV59217681; called by muse, mutect2, varscan2
- COL6A2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as COSV55997812; called by muse, mutect2
- DNAH11 | c.8712G>C p.K2904N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV60936967; called by muse, mutect2, varscan2
- FBXL19 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.114); catalogued as rs202132610, COSV57940426; called by muse, mutect2, varscan2
- KDM5C | c.2437C>T p.Q813* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100948921, COSV64762376; called by muse, mutect2, varscan2
- PCDHB7 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.803); catalogued as COSV50753487; called by muse, mutect2, varscan2
- RAMP1 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1297209097, COSV54537331; called by muse, mutect2, varscan2
- RNF123 | c.274T>C p.S92P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as COSV59683836; called by muse, mutect2, varscan2
- RPL4 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV100331186, COSV57206205; called by muse, mutect2, varscan2
- SAMD11 | c.1534C>A p.P512T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100497936; called by muse, varscan2
- SAMD11 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs181205550, COSV58985687; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPAG17 | c.3299A>C p.E1100A | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV60452118; called by muse, mutect2, varscan2
- TATDN1 | c.808A>G p.M270V | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52677328; called by muse, mutect2, varscan2
- TTN | c.4049G>A p.R1350H (on ENST00000591111; = p.R1304H on NM_003319.4) | Missense Mutation (SNP) | VAF 29/126 reads (23%) | PolyPhen probably damaging (0.998); catalogued as rs539470256, COSV59861393; ClinVar: likely benign; called by muse, mutect2, varscan2
- UGT1A6 | c.514A>G p.R172G | Missense Mutation (SNP) | VAF 77/290 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV59380693; called by muse, mutect2, varscan2
- UPF2 | c.2002C>A p.R668S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62657685, COSV62661464, COSV62664592; called by muse, mutect2, varscan2
- ZBED6CL | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs756908891, COSV59604412; called by muse, mutect2, varscan2
- ZNF257 | c.932C>T p.T311I | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs368126672, COSV104436098; called by muse, mutect2, varscan2
- ZSWIM8 | c.1678C>A p.Q560K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.142); catalogued as COSV67130899; called by muse, mutect2
- ACVR1B | c.1009_1010del p.K337Vfs*24 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | called by mutect2, pindel, varscan2
- LILRA1 | c.1009del p.A337Pfs*6 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- PHF1 | c.952dup p.S318Ffs*6 | Frame Shift Ins (INS) | VAF 30/192 reads (16%) | called by mutect2, pindel, varscan2
- RNPEP | c.1376del p.Y459Sfs*25 | Frame Shift Del (DEL) | VAF 60/290 reads (21%) | called by mutect2, pindel*, varscan2
- TMEM19 | c.542_554del p.A181Efs*12 | Frame Shift Del (DEL) | VAF 40/190 reads (21%) | called by mutect2, pindel, varscan2
- EMILIN3 | c.2161A>C p.R721= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV60034894; called by muse, mutect2, varscan2
- HTT | c.5751G>T p.T1917= | Silent (SNP) | VAF 33/172 reads (19%) | catalogued as rs761470964, COSV61856693, COSV61863014; called by muse, mutect2, varscan2
- IPO11 | c.1026C>T p.S342= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV57571545; called by muse, mutect2, varscan2
- KAT8 | c.1038C>T p.V346= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs757723541, COSV54894886; called by muse, mutect2
- LBR | c.1131A>T p.R377= | Silent (SNP) | VAF 39/200 reads (20%) | catalogued as COSV55287108; called by muse, mutect2, varscan2
- NDFIP2 | c.363G>A p.E121= | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as COSV54526456; called by muse, mutect2, varscan2
- NEB | c.2097A>G p.Q699= | Silent (SNP) | VAF 54/230 reads (23%) | catalogued as COSV50805860; called by muse, mutect2, varscan2
- RUSC1 | c.342C>A p.P114= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV52737967, COSV99429830; called by muse, mutect2, varscan2
- SLC22A12 | c.498C>A p.A166= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV60570684; called by muse, mutect2, varscan2
- TET1 | c.1158T>A p.G386= | Silent (SNP) | VAF 12/399 reads (3%) | catalogued as COSV65381603; called by muse, mutect2
- TMED2 | c.93G>A p.E31= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV51628248; called by muse, mutect2, varscan2
- ZNF528 | c.708T>C p.T236= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as COSV64618203; called by muse, mutect2, varscan2
- NFYC | c.388-804_388-803insGTG | Intron (INS) | VAF 10/60 reads (17%) | called by mutect2, pindel*, varscan2
